Somatic mutation profile of tumor specimen TARGET-10-PARSKH-09A (aliquot TARGET-10-PARSKH-09A-01D) from TARGET case TARGET-10-PARSKH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.9 years (5,436 days).
Specimen TARGET-10-PARSKH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4015d973-0c56-468d-9814-782d17b92e88.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARSKH-10A (Blood Derived Normal), aliquot TARGET-10-PARSKH-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f384e60-e5dd-45a9-ac79-fd3f7abf5d88

The open-access MAF lists 20 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Intron 4, Silent 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF38 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 68/76 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200268389, COSV54440792; called by muse, mutect2, varscan2
- CACNB2 | c.511G>A p.G171R (on ENST00000324631 / NM_201596.3; = p.G116R on NM_000724.4) | Missense Mutation (SNP) | VAF 106/182 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs766267727, COSV56612231; called by muse, mutect2, varscan2
- CFAP65 | c.360C>T p.P120= (on ENST00000341552 / NM_194302.4; = p.P55= on NM_152389.4) | Splice Region (SNP) | VAF 8/48 reads (17%) | catalogued as rs368785817; called by muse, mutect2, varscan2
- FTCD | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748347001; called by muse, mutect2, varscan2
- HDC | c.874G>A p.G292R | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51068294, COSV99984138; called by muse, mutect2, varscan2
- KCNN2 | c.1693C>T p.R565W (on ENST00000264773; = p.R777W on NM_021614.4) | Missense Mutation (SNP) | VAF 93/97 reads (96%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.973); catalogued as rs79675198, COSV53283201; called by muse, mutect2, varscan2
- KIF2B | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as COSV52127166; called by muse, mutect2, varscan2
- MAPK1 | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 120/127 reads (94%) | SIFT tolerated (0.63); PolyPhen benign (0.023); catalogued as COSV53184882; called by muse, mutect2, varscan2
- SLC20A1 | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 120/122 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55610211; called by muse, mutect2, varscan2
- ARHGAP31 | c.2144T>G p.L715R | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2
- DNHD1 | c.7048C>G p.L2350V | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- GREB1L | c.3944G>A p.R1315Q | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- LZTR1 | c.280_281insCCCCC p.D94Afs*9 | Frame Shift Ins (INS) | VAF 56/57 reads (98%) | called by mutect2, pindel, varscan2
- TET3 | c.3329T>C p.L1110P | Missense Mutation (SNP) | VAF 71/75 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5AS1 | c.120C>T p.V40= | Silent (SNP) | VAF 122/128 reads (95%) | catalogued as COSV57980801; called by muse, mutect2, varscan2
- WDFY4 | c.8859C>A p.T2953= | Silent (SNP) | VAF 10/198 reads (5%) | catalogued as COSV55422322; called by muse, mutect2
- AGO3 | c.1030-43A>G | Intron (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- KTN1 | c.3771+67A>T | Intron (SNP) | VAF 10/87 reads (11%) | called by muse, mutect2
- TMEM63B | c.1413+123C>T | Intron (SNP) | VAF 35/77 reads (45%) | called by muse, mutect2, varscan2
- ZCRB1 | c.113+23G>T | Intron (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
